Somatic mutation profile of tumor specimen TARGET-30-PANXJL-01A (aliquot TARGET-30-PANXJL-01A-01D) from TARGET case TARGET-30-PANXJL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Pelvic lymph nodes; Age at diagnosis: 15.7 years (5,734 days).
Specimen TARGET-30-PANXJL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d980ae8d-e3b6-461e-a1f8-874e0a84c3bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANXJL-10A (Blood Derived Normal), aliquot TARGET-30-PANXJL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef10514a-ba0c-4a7c-8ff8-6c9022f4b157

The open-access MAF lists 24 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 1, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- AGBL2 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV54089721; called by muse, mutect2, varscan2
- ALMS1 | c.10480C>G p.Q3494E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs772624348, CD150744, CM020923, COSV52501343; called by muse, mutect2, varscan2
- ANAPC5 | c.299T>G p.M100R | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs199951770, COSV55841261; called by muse, mutect2, varscan2
- CHD6 | c.2477A>G p.Y826C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs565086652, COSV58553292; called by muse, mutect2, varscan2
- CHP2 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs138042112; called by muse, mutect2, varscan2
- DNAH3 | c.9031G>A p.A3011T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs746811682, COSV54500830; called by muse, mutect2, varscan2
- EPHB1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775406650, COSV67652905; called by muse, mutect2, varscan2
- EXPH5 | c.5026A>G p.T1676A | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs1037665956, COSV56198418; called by muse, mutect2, varscan2
- GPC2 | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52783666; called by muse, mutect2, varscan2
- LUZP2 | c.858+1G>T p.X286_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV61193696; called by muse, mutect2, varscan2
- MROH9 | c.571T>A p.S191T | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.6); catalogued as COSV63009494; called by muse, mutect2, varscan2
- PKHD1L1 | c.10148G>T p.R3383L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV65736053, COSV65745730; called by muse, mutect2
- PRKCG | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1165667637, COSV54723134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RLN1 | c.436T>G p.S146A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as COSV56346052, COSV56346223; called by muse, mutect2, varscan2
- SAMD9L | c.4510A>G p.N1504D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV59079099; called by muse, mutect2, varscan2
- SIGLEC1 | c.3971G>T p.C1324F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568839427, COSV52458000; called by muse, mutect2
- STON1 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150265234, COSV59125538; called by muse, mutect2, varscan2
- TSC1 | c.3409G>A p.G1137S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as COSV53763194; called by muse, mutect2, varscan2
- ZNF425 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV65200489; called by muse, mutect2, varscan2
- HLA-C | c.967G>T p.V323F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- OR5I1 | c.789del p.S265Afs*23 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- SLC35G1 | c.426C>T p.T142= (on ENST00000427197 / NM_001134658.3; = p.T141= on NM_153226.4) | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs757889656, COSV65055020; called by muse, mutect2, varscan2
- SNORA71B | n.87A>C | RNA (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
